Gene-level copy-number profile of tumor specimen BLGSP-71-23-00405-01A from CGCI case BLGSP-71-23-00405, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 60.2 years (21,987 days).
Specimen BLGSP-71-23-00405-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d4431e11-102b-4b3e-ab90-1e0edb7ea9f8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-23-00405-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/e352e26e-e812-4602-b61f-e36646eac1d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 220; copy number 1: 5,224; copy number 2: 50,772; copy number 3: 2,322; copy number 4: 321; copy number 5: 22; copy number 6: 2; copy number 7: 3; copy number 9: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 220 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,415,352–70,448,015, 1 gene: GTF2H2B.
- chr6:26,021,649–26,453,415, 46 genes: H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9, H3C8, H2AC10P, H2BC10, H4C8, H3C9P, BTN3A2, BTN2A2, BTN3A1, BTN2A3P, BTN3A3.
- chr6:26,501,221–26,546,933, 4 genes: BTN1A1, RNU6-502P, HCG11, HMGN4.
- chr6:27,810,064–27,897,566, 16 genes: H3C10, H2AC14, H2BC14, H4C11, H4C12, H2BC15, H2AC15, H2BC16P, H2AC16, H1-5, H3C11, H4C13, H3C12, H2AC17, H2BC17, RNU7-26P.
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,892,188–25,089,151, 28 genes (within-gene range 0–1): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.
- chr17:65,009,289–65,056,740, 2 genes (within-gene range 0–2): GNA13, AC037487.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,219,918–70,258,930, 1 gene, copy number 9: GUSBP14.
- chr5:70,449,636–70,479,215, 2 genes, copy number 6: AC146944.2, NAIPP1.
- chr9:6,645,956–6,727,438, 7 genes, copy number 5 (within-gene range 3–5): AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr13:99,606,669–99,957,167, 7 genes, copy number 5: CLYBL, MIR4306, CLYBL-AS2, CLYBL-AS1, AL137139.1, AL137139.3, AL137139.2.
- chr16:32,715,931–32,788,944, 8 genes, copy number 5: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr16:33,533,816–33,570,935, 4 genes, copy number 7–10: AC136944.1, AC136944.2, AC136944.4, AC136944.3.

Autosomal genes at a single copy (total copy number 1): 2,368. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
